Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4326, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4326-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

Left kidney tumor. Left partial nephrectomy.

Specimens Submitted:

1: SP: Left renal hilar lymph nodes

2: SP: Left kidney mass

DIAGNOSIS:

- 1) LYMPH NODES, LEFT RENAL HILAR; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 2) KIDNEY, LEFT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE II/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR'S GREATEST DIAMETER IS 6.3 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL SCLEROSIS AND CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS NOT SUBMITTED.

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Left Renal Hilar Lymph Nodes". It consists of soft fibroadipose tissue with lymph nodes measuring 2.5 x 2 x 1 cm. Three lymph nodes are identified. The entire lymph nodes are submitted in three blocks for frozen section.

Summary of Sections:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

FSC - frozen section control (one bisected lymph node)
FSCA - frozen section control (one bisected lymph node)
FSCB - frozen section control (one lymph node)

2) The specimen is received fresh for frozen section, labeled "Left Kidney Mass". It consists of one partial nephrectomy specimen measuring 10 x 8 x 6 cm. Margins are partially inked black. The specimen is serially sectioned to reveal a portion of kidney measuring 7.5 x 6.5 x 5.5 cm. Approximately 70% of the kidney is replaced by a very demarcated mass measuring 6.3 x 5.8 x 5.8 cm. The mass shows variegated cut surfaces with hemorrhage, necrosis and cystic formation. The mass is located beneath the renal capsule, approximately 0.8 cm from the soft tissue resection margin, 1 cm from the kidney resection margin. One yellow satellite nodule measuring 0.6 cm in greatest dimension is located approximately 0.4 cm from the main mass and 0.8 cm from the kidney resection margin. A portion of perirenal fibroadipose tissue measuring approximately 10 x 8 x 2.5 cm is attached and is not involved by the tumor. A gross photograph is taken. Representative sections are submitted in eight blocks.

Summary of Sections:

FSC - frozen section control
NM - satellite nodule with kidney margin
TKM - tumor with kidney and adjacent margin

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSCA	1	2		Y
	FSCB	1	2		
	FSCC	1	1		
2	FSC	1	M		N
	NM	1	1		
	TKM	6	M		

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODES (0/3).
(NEGATIVE FOR CARCINOMA. NO CARCINOMA SEEN). SINUSOIDAL SPINDLE CELL PROLIFERATION SUGGESTIVE OF VASCULAR TRANSFORMATION OF SINUS. (RD)
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR FAVOR CONVENTIONAL RENAL CELL CARCINOMA. MARGINS UNINVOLVED.
(RD)
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 299a3250-13b4-4624-8c7f-eb85b1c34fa2 (TCGA-BP-4326.3198A500-A873-432B-98C9-D978C866037D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).